Somatic mutation profile of tumor specimen 0DA0UV from CCDI case PBBJKN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,123 days).
Specimen 0DA0UV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70ba6ce1-db25-436c-a718-02eab2b62fd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA0UW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91e2aea7-23bb-46c1-96c7-8c9fd6168099

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SDHA | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 135/516 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1553999752, CM003899; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AP4B1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs149723440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FYCO1 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376165229; called by muse, mutect2, varscan2
- MRGPRE | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.627); catalogued as COSV67745840; called by muse, mutect2, varscan2
- WNK1 | c.5279C>T p.P1760L (on ENST00000315939 / NM_018979.4; = p.P1513L on NM_014823.3) | Missense Mutation (SNP) | VAF 23/271 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs141202956; ClinVar: uncertain significance; called by muse, mutect2
- HEPH | c.2073C>A p.N691K (on ENST00000343002; = p.N424K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2
- KITLG | c.124A>G p.K42E | Missense Mutation (SNP) | VAF 94/420 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- MAGEE1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2
- SARS1 | c.190dup p.I64Nfs*14 | Frame Shift Ins (INS) | VAF 56/259 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.4869C>A p.I1623= | Silent (SNP) | VAF 35/234 reads (15%) | called by muse, mutect2, varscan2
- BTBD11 | c.2049C>T p.G683= (on ENST00000280758 / NM_001018072.2; = p.G220= on NM_001017523.2) | Silent (SNP) | VAF 60/372 reads (16%) | catalogued as rs373750144, COSV55023936; called by muse, mutect2, varscan2
- CD7 | c.222C>T p.D74= | Silent (SNP) | VAF 52/451 reads (12%) | catalogued as rs367694038, COSV53938753; called by muse, mutect2, varscan2
- ECEL1 | c.1692G>A p.L564= | Silent (SNP) | VAF 18/374 reads (5%) | called by muse, mutect2
- PCDHB16 | c.1362C>A p.T454= | Silent (SNP) | VAF 34/165 reads (21%) | called by muse, mutect2, varscan2
